Somatic mutation profile of tumor specimen TCGA-4V-A9QN-01A (aliquot TCGA-4V-A9QN-01A-11D-A423-09) from TCGA case TCGA-4V-A9QN, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 40.6 years (14,825 days).
Specimen TCGA-4V-A9QN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3ca9c94-01d7-4f7e-8c23-9a91ad6c986c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4V-A9QN-11A (Solid Tissue Normal), aliquot TCGA-4V-A9QN-11A-11D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc32829b-146d-4b44-ab3e-9227f0e06060

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD17 | c.369_374del p.D123_D124del | In Frame Del (DEL) | VAF 22/44 reads (50%) | catalogued as rs746084804; called by mutect2, varscan2
- KCNV2 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs375827258; called by muse, mutect2, varscan2
- PI16 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs1369919578, COSV65321183; called by muse, mutect2, varscan2
- TSSK1B | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs556130601, COSV101180947; called by muse, mutect2, varscan2
- GLI2 | c.2371A>G p.S791G (on ENST00000361492 / NM_001374353.1; = p.S808G on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NR2F2 | c.316A>C p.S106R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- RLIM | c.166_169+17delinsATG p.X56_splice | Splice Site (DEL) | VAF 35/110 reads (32%) | called by pindel, varscan2*
- LILRB4 | c.600C>A p.G200= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs770797109; called by muse, mutect2
- XPO1 | c.3117A>G p.E1039= | Silent (SNP) | VAF 30/51 reads (59%) | called by muse, mutect2, varscan2
